Surgical pathology report (de-identified scan), TCGA case TCGA-H8-A6C1, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-H8-A6C1-01A (Primary Tumor).

[page 1 of 4]
Clinical Information:

Pancreatic cancer

Operative Procedure:

Laparoscopic Whipple

Pre-Operative Diagnosis:

Pancreatic cancer

Specimen Received:

- A: whipple specimen - (short black - panc. neck , long black - uncinata , blue
- bile duct) (FS)
B: Gallbladder
C: portal lymph node
D: SMA tissue

Final Pathologic Diagnosis:

A. Pancreas, Whipple resection:

Specimen: Head of pancreas; Duodenum; Gallbladder
Procedure: Pancreaticoduodenectomy (Whipple resection);

Cholecystectomy

Tumor site: Pancreatic head
Tumor size: 3.1 x 2.1 x 1.1 cm (greatest dimensions)
Tumor focality: Unifocal
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated (G2)
Microscopic tumor extension: Tumor invades peripancreatic soft tissue and
duodenal wall

Margins

Margins uninvolved by tumor
Distance of tumor from closest margin: 4 mm
Specify margin: Uncinate

Lymph-vascular invasion: Not identified

Perineural invasion: Identified

Pathologic Staging (pTNM)

TNM descriptors: none known
Primary tumor (pT): pT3
Regional lymph nodes (pN): pN0
Number examined: 21
Number involved: 0
Distant metastasis (pM): pMX

ICD-O-3
Adenocarcinoma NOS
8140/3
Site: Head of pancreas
C25.0
JW 5/24/13

Criteria	lw 5/10/13	Yes	No
Histology Discrepancy			
Error: Malignancy History			
Reviewer Initials	AW	DISAPPROVED	

[page 2 of 4]
Additional pathologic findings: Chronic pancreatitis, duodenal ulcer with reactive changes, Submucosal lipoma of duodenum (2nd lesion noted in gross description).

B. Gallbladder, cholecystectomy:

Chronic cholecystitis.

Two lymph nodes, no evidence of malignancy (0/2).

C. Lymph node, portal, resection:

Two lymph nodes, no evidence of malignancy (0/2).

D. SMA tissue, resection:

No evidence of malignancy (2 lymph nodes).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: Whipple:

FSA1: Bile duct:

Negative for carcinoma.

FSA2: Uncinate:

Negative for carcinoma.

FSA3: Neck:

Negative for carcinoma.

F/S TAT: 33 mins.

Gross Description:

Received are four containers, all labeled with the patient's name

Part A is received fresh for frozen section diagnosis and additionally labeled "Whipple specimen, long black=uncinate, short black=pancreatic neck, blue=bile duct."

Specimen (components and dimensions): The specimen is the product of a Whipple resection, previously sectioned, consisting of a 13.2 x 3.0 cm duodenum with pancreatic head 4.7 cm in length and additional dimensions of 5.6 x 5.5 cm.

Gallbladder: The gallbladder is submitted as a separate specimen (see part B).

Specimen inking pattern: Uncinate/retroperitoneal/posterior black, vascular groove red, anterior-blue. (Please note the specimen has been previously inked in focal areas: The bile duct inked blue, uncinate inked yellow, neck inked black.)

Tumor:

Location: Pancreatic head

Size: 3.1 x 2.1 x 1.1 cm

Appearance: The tumor is white-tan to tan with ill defined borders and a decrease in lobular architecture. The tumor is also firm.

[page 3 of 4]
Gross impression of invasive growth: There is a biliary stent present in the bile duct. After removal, the tumor appears to abut and obstruct the bile duct. The tumor appears to possibly abut the main pancreatic duct, however, there does not appear to be any gross involvement and the pancreatic duct is of the usual caliber. The tumor also appears to abut, but not grossly penetrate through the vascular groove. Please defer to microscopic diagnosis.

Resection margins (closest):

Proximal duodenum or stomach: 2.1 cm

Distal duodenum: 7.4 cm

Bile duct: 2.9 cm

Pancreatic neck/duct: 2.3 cm

Uncinate/Retroperitoneum: 1.1 cm

Other findings: The attached portion of duodenum has a pink-tan to brown, smooth and roughened serosal surface. There appears to be a 1.1 x 0.8 cm transmural defect located 5.4 cm from the proximal end. Upon opening the duodenum, the mucosa is pink-tan with the normal mucosal folds. The area of transmural defect seems to be the area opposing where the bile duct stent was located. This could be a possible area of local trauma. There are two lesions present on the duodenal mucosal surface. The first lesion is approximately 2.6 cm from the proximal duodenal margin. This lesion is concerning for possible tumor. The lesion appears separate from the ampulla, located on the posterior wall of the duodenum. This lesion has dimensions of 1.4 x 1.4 x 0.4 cm. The lesion is pink-tan with raised borders with a central ulcerated area.

Representative sections of the first lesion are placed in cassettes A14 and A15.

The second lesion in the duodenum is approximately 4.6 cm from the proximal surface, also located on the posterior wall of the duodenum. This lesion has dimensions of 1.4 x 1.3 x 0.8 cm. This lesion is pink-tan with a smooth surface. The cut surface of this lesion is yellow-tan and homogeneous. Representative sections of this lesion are placed in cassettes A16 and A17.

The bile duct is removed and submitted for frozen section diagnosis (FSA1). The tissue is resubmitted for permanent section in cassette A1. The uncinate margin is shaved off and submitted for frozen section diagnosis (FSA2) and this tissue is resubmitted for permanent section in cassette A2. The pancreatic neck is shaved off and submitted for frozen section diagnosis (FSA3) and this tissue is resubmitted for permanent section in cassette A3.

Block List:

- A1 bile duct margin;
- A2 uncinate margin;
- A3 pancreatic neck margin;
- A4 proximal duodenal margin;
- A5 distal duodenal margin;
- A6 ampulla;
- A7 mass to vascular groove;
- A8-10 representative sections of tumor;
- A11 tumor to bile duct;
- A12 tumor to pancreatic duct;

[page 4 of 4]
- A13 tumor to uncinata;
- A14-15 representative sections of first lesion in duodenum;
- A16-17 representative sections from second lesion in duodenum;
- A18 one possible lymph node bisected;
- A19 one possible lymph node bisected;
- A20 one possible lymph node submitted in toto;
- A21 one possible lymph node bisected;
- A22 one possible lymph node bisected;
- A23 one possible lymph node bisected;
- A24 one possible lymph node;
- A25 one possible lymph node bisected;
- A26 one possible lymph node;
- A27 one possible lymph node;
- A28 one possible lymph node;
- A29 one possible lymph node;
- A30 one possible lymph node;
- A31 one possible lymph node;
- A32 one possible lymph node;
- A33 one possible lymph node;
- A34 one possible lymph node;
- A35 one possible lymph node;
- A36 one possible lymph node bisected.

Part B is received in formalin additionally labeled "gallbladder" and consists of a gallbladder with overall dimensions of 5.9 x 2.5 x 1.7 cm. The surface is purple-tan, smooth to roughened. There is a pericystic duct lymph node identified, having a greatest dimension of 0.6 cm. Opening of the gallbladder reveals a moderate amount of yellow-green markedly viscid bile. There are no choleliths identified. The mucosa is pink-tan to brown with focal yellow stippling. The thickness of the gallbladder wall is 0.3 cm. The cystic duct is probe patent and appears slightly thickened. The usual sections are submitted in a single cassette to include the pericystic duct lymph node.

Part C is received in formalin additionally labeled "portal lymph node" and consists of one pink-tan irregular fragment of soft tissue, having dimensions of 1.3 x 0.8 x 0.3 cm. The specimen is submitted in toto in cassette C.

Part D is received in formalin additionally labeled "SMA tissue" and consists of two pink-tan irregular fragments of soft tissue, having dimensions of 1.6 x 0.7 x 0.4 cm and 1.9 x 0.5 x 0.3 cm. The specimen is submitted in toto in cassette D.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

DOB:

Gender: M

Source: NCI Genomic Data Commons file 072dcb37-1df0-4226-acd7-718aad789a66 (TCGA-H8-A6C1.719BE4BC-2FEB-4AB4-8F9E-D1BBD7085975.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).